Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO3, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAO3-01A (Primary Tumor).

[page 1 of 2]
Name:

Sex:

ICD-0-3
Seminoma NOS 9061/3
Site R Testis NOS 962.9
03/31/14

- Specimen Source: RIGHT TESTICULAR MASS
- Gross Exam Date:
- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA (9.5 cm), right testis, procedure not stated.. (See note)
2. LYMPHOVASCULAR INVASION NOTED. (See note)
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR.
6. pT2NXMX
7. TESTICULAR TISSUE WITH TUBULAR ATROPHY AND WITHOUT EVIDENCE OF SPERMATOGENESIS.

Note: Although the clusters of malignant cells seen in lymphovascular spaces may represent carry over artifact the possibility of vascular invasion at these sites cannot be ruled out. Clinical correlation recommended. Tumor cells positive for PLAP and negative for CAM 5.2 and AE1/AE3. , nurse practitioner from urology
clinic notified at from urology
will be informed.

GROSS DESCRIPTION:

The specimen is received in one part unfixed labeled with the patient's name, and "right testicular mass". It consists of a 350-gram orchiectomy specimen including 9.6 x 7.6 x 5.2-cm testis, 2 x 1.5 x 0.7-cm epididymis and 10-cm in length and 1.6-cm in diameter spermatic cord. The specimen is inked black. On sectioning the entire testis appears replaced by a white-tan fleshy well-circumscribed mass measuring 9.5 x 6 x 4.5-cm. At its closest approach the lesion is 0.5 cm from the epididymis and 0.1 cm from the tunica albuginea. There is no gross involvement of the tunica albuginea or impingement on the epididymis. No rim of testicular parenchyma is grossly identifiable. The spermatic cord consists of a vas deferens, arteries and veins and is unremarkable. Representative sections are submitted. Summary of cassettes: Cassette 1 - Spermatic cord resection margin. Cassette 2 - Spermatic cord mid

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
SURGICAL PATHOLOGY TISSUE REPORT

Name:

Sex:

- Specimen Source: RIGHT TESTICULAR MASS
- Gross Exam Date:
- Physician:

Pager No.:

portion. Cassette 3 - Spermatic cord paratesticular portion.
Cassettes 4 and 5 - Tumor and tunica albuginea. Cassettes 6 and 7 -
Tumor. Cassette 8 - Tumor and adjacent testis. Cassettes 9 and 10 -
Tumor and base of epididymis. R10.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 2

Source: NCI Genomic Data Commons file 6ebbad0f-29d6-4825-879a-8176c81b9825 (TCGA-XE-AAO3.6EA845DD-E7DC-4E7A-98AB-A9E36668CB18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).